Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A2N8, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A2N8-01A (Primary Tumor).

ADDENDA:**Addendum****MOLECULAR ANATOMIC PATHOLOGY TESTING:**

1.4 cm tumor:

A. *NRAS* codon 61 mutation IDENTIFIED.

Collection Date:

B. Mutations in *BRAF*, *HRAS61*, *KRAS12/13* and *RET/PTC1* and *RET/PTC3* rearrangements NOT identified.**NOTE:**

Nucleic acids were extracted in the amount sufficient for testing.

1.0 cm tumor:

Mutational status for *BRAF*, *NRAS61*, *HRAS61*, *KRAS12/13* and *RET/PTC1* and *RET/PTC3* rearrangements is INDETERMINATE due to insufficient material for testing.**NOTE:**

Low concentration of nucleic acids was extracted due to extensive degenerative changes and limited amount of viable tumor cells available for the analysis. Amplification of the DNA for *BRAF*, *NRAS61*, *HRAS61*, *KRAS12/13* was insufficient for the analysis. Amplification of the RNA for the *GAPDH* and *KRT7* genes was insufficient for the analysis.

FINAL DIAGNOSIS:**THYROID, TOTAL THYROIDECTOMY (13 GRAMS) -**

A. PAPILLARY THYROID CARCINOMA, TWO (2) FOCI (1.4 AND 1.0 CM) IN THE RIGHT LOBE AND ISTHMUS, CONFINED TO THYROID.

I. LARGEST FOCUS: CONVENTIONAL TYPE WITH CALCIFICATION AND OSSIFICATION.

II. 1.0 CM FOCUS: CONVENTIONAL TYPE WITH PROMINENT FOLLICULAR PATTERN.

B. RARE PSAMMOMA BODY PRESENT IN A LYMPHATIC.

C. TWO LYMPH NODES, ISTHMUS, NO TUMOR PRESENT (0/2).

D. PATHOLOGIC STAGE: pT1bN0.

F. NORMOCELLULAR PARATHYROID TISSUE IN RIGHT LOBE.

**COMMENT:**

Molecular studies will be performed and the results will be reported as an addendum.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY THYROID TUMORS**

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Right Lobe, Isthmus
TUMOR FOCALITY: Multifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 1.4 cm
HISTOLOGIC TYPE:** Papillary carcinoma
PRIMARY TUMOR (pT): pT1b
REGIONAL LYMPH NODES (pN): pN0

Number of regional lymph nodes examined: 2

Number of regional lymph nodes involved: 0

DISTANT METASTASIS (pM): Not applicable**EXTRATHYROIDAL EXTENSION:** Not identified**MARGINS:** Margins uninvolved by carcinoma**LYMPH-VASCULAR INVASION:** Present**Comment:** Psammoma bodies in lymphatics considered positive for angiolymphatic invasion

1CD-0-3

carcinoma, papillary, thyroid 8260/3
Site: thyroid, nos c73.9

lw
8/18/11

lw 8/18/11

Source: NCI Genomic Data Commons file 22eadea7-d15d-42c2-99ea-d1b1b90091fb (TCGA-BJ-A2N8.8ED5135F-45E6-4B1D-813C-64D3E86EC9AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).